Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA81, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA81-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Bladder
Bladder + prostate
Papillary urothelial high grade carcinoma.
Tumor limited to the bladder and with infiltration to the outer third of the muscular
propria.
Angiovascular invasion: not detected.
Lymphatic vessels invasion: not detected.
Blood vascular invasion: not detected.
Surgical margins absent of neoplastic involvement.
Nonspecific chronic prostatitis.
Nodular hyperplasia of the prostate.
Deferens and seminal vesicles uninvolved by neoplasia.

ICD-O-3
Carcinoma, urothelial papillary
C67.4 8/30/13
Site: Bladder, posterior wall
path C67.4
Bladder NOS C67.9
JW 8/18/14

Source: NCI Genomic Data Commons file 622faf62-cd41-4e93-ad57-d96f5e87b2e6 (TCGA-4Z-AA81.715A2080-BE4D-4A75-B7A7-C68FD032997E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).